Somatic mutation profile of tumor specimen TCGA-RD-A8N4-01A (aliquot TCGA-RD-A8N4-01A-21D-A364-08) from TCGA case TCGA-RD-A8N4, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 58.4 years (21,324 days).
Specimen TCGA-RD-A8N4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92c0988a-e39f-4561-be8d-093c6b86a199.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RD-A8N4-10A (Blood Derived Normal), aliquot TCGA-RD-A8N4-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9f658a6-7d26-40fa-9699-0e2cc1a05614

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP58 | c.2191C>T p.H731Y | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs751343572, COSV100866041; called by muse, mutect2
